Gene-level copy-number profile of tumor specimen ALCH-AEUL-TTP1-A from ALCHEMIST case ALCH-AEUL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.1 years (25,225 days).
Specimen ALCH-AEUL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file be3dd25a-5750-4b74-a656-3e56c6be72f5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEUL-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/5aa735c5-14f4-444e-8354-f1cc76bc1346

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 1,034; copy number 2: 12,709; copy number 3: 19,186; copy number 4: 18,980; copy number 5: 4,994; copy number 6: 1,025; copy number 7: 393; copy number 8: 11; copy number 9: 6; copy number 10: 1; copy number 12: 4; copy number 13: 14; copy number 14: 8; copy number 16: 13; copy number 24: 1.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:137,411–182,399, 3 genes (within-gene range 0–1): AC026369.1, AC026369.2, AC007406.3.
- chr12:193,036–194,130, 1 gene (within-gene range 0–1): AC007406.1.
- chr16:55,760,566–55,793,960, 1 gene: CES1P1.
- chr18:109,065–122,219, 2 genes: ROCK1P1, MIR8078.
- chr19:19,254,748–19,273,391, 4 genes (within-gene range 0–4): AC138430.1, HAPLN4, AC138430.2, TM6SF2.
- chr22:18,524,620–18,530,573, 3 genes: Metazoa_SRP, AC023490.3, TMEM191B.
- chr22:18,650,023–18,653,617, 1 gene: PPP1R26P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 451 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,175,748–149,705,716, 14 genes, copy number 13 (within-gene range 2–13): AC245297.3, AC245297.1, AC245297.2, 7SK, SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19, PPIAL4C, LINC00869, AC242842.2, AC242842.1, RNVU1-30, FAM91A2P.
- chr1:223,947,605–223,950,416, 1 gene, copy number 7: CICP5.
- chr5:58,198–693,352, 27 genes, copy number 7–9: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1.
- chr5:1,456,480–26,399,819, 351 genes, copy number 7 (broad region; genes not listed).
- chr7:56,955,785–56,955,864, 1 gene, copy number 10: MIR4283-1.
- chr9:137,554,444–137,590,512, 2 genes, copy number 9: DPH7, ZMYND19.
- chr14:18,333,726–18,650,966, 17 genes, copy number 7: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11.
- chr16:32,649,193–32,788,944, 13 genes, copy number 16: AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3, AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10.
- chr21:8,680,538–8,680,934, 1 gene, copy number 14: CR381572.2.
- chr21:44,107,373–44,262,216, 11 genes, copy number 8: PWP2, GATD3A, LINC01678, AP001056.2, AP001056.1, AP001057.1, ICOSLG, AP001059.2, AP001059.1, DNMT3L, DNMT3L-AS1.
- chr22:33,104,330–34,218,796, 13 genes, copy number 7–24 (within-gene range 2–24): LINC01640, Z82198.1, Z82198.3, LARGE1, Z82198.2, Z82173.1, MIR4764, SNORA50B, Z69713.1, LARGE-IT1, LARGE-AS1, Z73429.1, LINC01643.

Autosomal genes at a single copy (total copy number 1): 674. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
